Somatic mutation profile of tumor specimen TCGA-06-0744-01A (aliquot TCGA-06-0744-01A-01W-0348-08) from TCGA case TCGA-06-0744, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 67.0 years (24,471 days).
Specimen TCGA-06-0744-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9649d137-7ced-4854-99f1-987aacb7596d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0744-10A (Blood Derived Normal), aliquot TCGA-06-0744-10A-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b2effc6a-808e-4ed2-8b2d-f768167f24c6

The open-access MAF lists 89 somatic variants for this specimen: 68 protein-altering or splice-affecting, 21 silent.
By variant classification: Missense Mutation 48, Silent 21, Frame Shift Ins 12, Nonsense Mutation 4, Frame Shift Del 2, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 139/349 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AC134980.2 | c.598G>A p.V200I | Missense Mutation (SNP) | VAF 109/152 reads (72%) | SIFT tolerated (0.53); PolyPhen benign (0.075); catalogued as rs375688421, COSV60906944; called by muse, mutect2, varscan2
- ADAM29 | c.519C>A p.C173* | Nonsense Mutation (SNP) | VAF 122/361 reads (34%) | catalogued as COSV63663937; called by muse, mutect2, varscan2
- ADAMTS12 | c.3139G>A p.A1047T | Missense Mutation (SNP) | VAF 277/699 reads (40%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV61263771; called by muse, mutect2, varscan2
- ADGRF4 | c.738C>A p.H246Q | Missense Mutation (SNP) | VAF 69/236 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.035); catalogued as COSV51952711; called by muse, mutect2, varscan2
- ADRA1B | c.978dup p.D327Rfs*134 | Frame Shift Ins (INS) | VAF 11/112 reads (10%) | catalogued as rs775788108; called by mutect2, pindel
- ARFGEF1 | c.4655dup p.P1553Tfs*7 | Frame Shift Ins (INS) | VAF 66/526 reads (13%) | catalogued as rs774148781; called by mutect2, varscan2
- ARHGEF35 | c.1283T>A p.L428H | Missense Mutation (SNP) | VAF 84/623 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.253); catalogued as COSV65312723; called by muse, mutect2, varscan2
- ARID4B | c.2739T>A p.D913E | Missense Mutation (SNP) | VAF 286/654 reads (44%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0.031); catalogued as COSV51603840; called by muse, mutect2, varscan2
- ATR | c.1276G>A p.G426R | Missense Mutation (SNP) | VAF 281/688 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.34); catalogued as COSV63386876; called by muse, mutect2, varscan2
- C2CD2L | c.1568G>A p.R523Q | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as rs750634362, COSV60884096; called by muse, mutect2, varscan2
- CCDC8 | c.1103G>A p.R368K | Missense Mutation (SNP) | VAF 107/344 reads (31%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.156); catalogued as COSV56773500; called by muse, mutect2, varscan2
- CENPE | c.2836G>A p.D946N | Missense Mutation (SNP) | VAF 336/791 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); catalogued as COSV54381733; called by muse, mutect2, varscan2
- CHST14 | c.1033dup p.R345Pfs*10 | Frame Shift Ins (INS) | VAF 8/92 reads (9%) | catalogued as rs774738190; called by mutect2, pindel
- DGKD | c.2916G>A p.M972I (on ENST00000264057 / NM_152879.3; = p.M928I on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 108/255 reads (42%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV51046687, COSV51049750; called by muse, mutect2, varscan2
- DOCK5 | c.1222G>A p.G408S | Missense Mutation (SNP) | VAF 74/173 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52402689; called by muse, mutect2, varscan2
- DOP1A | c.1063C>T p.R355C | Missense Mutation (SNP) | VAF 110/430 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52710715; called by muse, mutect2, varscan2
- EIF4G3 | c.247dup p.Q83Pfs*70 | Frame Shift Ins (INS) | VAF 20/140 reads (14%) | catalogued as rs755996348; called by mutect2, varscan2
- ELMO1 | c.842G>A p.R281Q | Missense Mutation (SNP) | VAF 156/231 reads (68%) | SIFT tolerated (0.32); PolyPhen benign (0.251); catalogued as rs746313086, COSV60305707; called by muse, mutect2, varscan2
- ELMO1 | c.284C>T p.S95L | Missense Mutation (SNP) | VAF 367/1371 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.03); catalogued as rs772235613, COSV60305715; called by muse, mutect2, varscan2
- EXOSC9 | c.1040G>C p.W347S | Missense Mutation (SNP) | VAF 112/283 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54666143; called by muse, mutect2, varscan2
- FIGN | c.799dup p.A267Gfs*100 | Frame Shift Ins (INS) | VAF 16/142 reads (11%) | catalogued as rs755527396; called by mutect2, varscan2
- GLYR1 | c.1140dup p.R381Afs*15 | Frame Shift Ins (INS) | VAF 44/214 reads (21%) | catalogued as rs749150409; called by mutect2, varscan2
- GYG2 | c.954dup p.P319Afs*14 | Frame Shift Ins (INS) | VAF 9/41 reads (22%) | catalogued as rs770047512; called by mutect2, varscan2
- GYPA | c.343C>T p.R115C | Missense Mutation (SNP) | VAF 398/943 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as rs572116498, COSV51626818; called by muse, mutect2, varscan2
- JAKMIP1 | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51533358; called by muse, mutect2
- KNG1 | c.1039-1G>A p.X347_splice | Splice Site (SNP) | VAF 268/556 reads (48%) | catalogued as COSV53978207; called by muse, mutect2, varscan2
- LRFN5 | c.1765G>A p.V589M | Missense Mutation (SNP) | VAF 139/285 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0.042); catalogued as rs772023044, COSV53257915; called by muse, mutect2, varscan2
- NHLRC1 | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1561882085; called by mutect2, varscan2
- NMUR2 | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 188/245 reads (77%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs759161756, COSV54919615; called by muse, mutect2, varscan2
- NSUN5 | c.337C>T p.R113W | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as rs781934018, COSV53091830; called by muse, mutect2, varscan2
- OR4A47 | c.182T>C p.L61P | Missense Mutation (SNP) | VAF 290/705 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV71444881; called by muse, mutect2, varscan2
- OR5I1 | c.21C>G p.N7K | Missense Mutation (SNP) | VAF 144/394 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV56887143; called by muse, mutect2
- OSMR | c.2017C>T p.P673S | Missense Mutation (SNP) | VAF 557/1628 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV57085713; called by muse, mutect2, varscan2
- PCDHA8 | c.1874G>T p.G625V | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.934); catalogued as rs1554139855, COSV65327415; called by muse, mutect2, varscan2
- PCDHB7 | c.1966G>A p.A656T | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.023); catalogued as rs782388523, COSV50763014; called by muse, mutect2, varscan2
- PIK3C2B | c.859dup p.R287Pfs*38 | Frame Shift Ins (INS) | VAF 48/308 reads (16%) | catalogued as rs749506841; called by mutect2, varscan2
- PMEPA1 | c.624dup p.S209Qfs*3 | Frame Shift Ins (INS) | VAF 22/132 reads (17%) | catalogued as rs751873496; called by mutect2, varscan2
- PON1 | c.892A>T p.N298Y | Missense Mutation (SNP) | VAF 146/488 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.144); catalogued as COSV55932100; called by muse, mutect2, varscan2
- PRCC | c.1138dup p.Q380Pfs*12 | Frame Shift Ins (INS) | VAF 105/692 reads (15%) | catalogued as rs778683789; called by mutect2, varscan2
- PSMB11 | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 58/120 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.045); catalogued as COSV68430212; called by muse, mutect2, varscan2
- RAB11FIP1 | c.2315C>T p.A772V | Missense Mutation (SNP) | VAF 65/180 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as rs371085767; called by muse, mutect2, varscan2
- RADX | c.1424C>T p.P475L | Missense Mutation (SNP) | VAF 369/414 reads (89%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV65318749; called by muse, mutect2, varscan2
- RIC8A | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as COSV100254741, COSV57315375; called by muse, varscan2
- RIMS2 | c.2944C>T p.R982* (on ENST00000666250 / NM_001348490.2; = p.R790* on NM_014677.5 and 7 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 325/808 reads (40%) | catalogued as rs201715496, COSV51684946; called by muse, mutect2, varscan2
- SAMD9 | c.1207G>T p.D403Y | Missense Mutation (SNP) | VAF 35/139 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV66075578; called by muse, mutect2, varscan2
- SERPINB4 | c.470-1G>A p.X157_splice | Splice Site (SNP) | VAF 196/527 reads (37%) | catalogued as COSV61985045; called by muse, mutect2, varscan2
- SLC22A8 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 56/109 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs936852997, COSV60325143; called by muse, mutect2, varscan2
- SMARCA4 | c.810dup p.G271Rfs*16 | Frame Shift Ins (INS) | VAF 4/21 reads (19%) | catalogued as rs1165714406; called by pindel, varscan2
- SPEG | c.421G>A p.V141M | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0.085); catalogued as COSV56669839; called by muse, mutect2, varscan2
- STAT6 | c.841dup p.Q281Pfs*92 | Frame Shift Ins (INS) | VAF 10/80 reads (13%) | catalogued as rs767674545; called by mutect2, varscan2
- TRIM10 | c.440A>G p.H147R | Missense Mutation (SNP) | VAF 118/250 reads (47%) | SIFT tolerated (0.41); PolyPhen benign (0.024); catalogued as rs759629347, COSV64989617; called by muse, mutect2, varscan2
- TRMO | c.889G>T p.V297F | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV64291905; called by muse, mutect2, varscan2
- TSPAN9 | c.262A>G p.I88V | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.67); PolyPhen benign (0.139); catalogued as rs1022296216, COSV50723984; called by muse, mutect2, varscan2
- TTN | c.88507C>T p.R29503W (on ENST00000591111; = p.R22079W on NM_003319.4) | Missense Mutation (SNP) | VAF 230/505 reads (46%) | PolyPhen probably damaging (0.999); catalogued as rs770088691, COSV60111692; called by muse, mutect2, varscan2
- UROC1 | c.1014C>G p.D338E | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.026); catalogued as COSV52033636; called by muse, mutect2, varscan2
- ZNF493 | c.1097G>A p.C366Y | Missense Mutation (SNP) | VAF 63/372 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV62750190; called by muse, mutect2, varscan2
- ZNF638 | c.4396G>A p.G1466R | Missense Mutation (SNP) | VAF 55/110 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52487973; called by muse, mutect2, varscan2
- ZNF98 | c.803G>A p.C268Y | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); catalogued as COSV100757585; called by mutect2, varscan2
- DICER1 | c.4588C>A p.P1530T | Missense Mutation (SNP) | VAF 50/1060 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2
- EPAS1 | c.1768C>A p.Q590K | Missense Mutation (SNP) | VAF 6/150 reads (4%) | SIFT tolerated (0.6); PolyPhen benign (0.039); called by muse, mutect2
- EPHA6 | c.291del p.C98Afs*17 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | called by mutect2, varscan2
- HDHD2 | c.723_726del p.Y241* | Frame Shift Del (DEL) | VAF 153/411 reads (37%) | called by pindel, varscan2
- KRT15 | c.221G>A p.G74D | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- PFKFB4 | c.1000G>T p.E334* | Nonsense Mutation (SNP) | VAF 10/152 reads (7%) | called by muse, mutect2
- PNISR | c.605C>T p.P202L | Missense Mutation (SNP) | VAF 8/216 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.006); called by muse, mutect2
- TRIM52 | c.410G>T p.G137V | Missense Mutation (SNP) | VAF 18/436 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); called by muse, mutect2
- UPF2 | c.2886G>A p.W962* | Nonsense Mutation (SNP) | VAF 14/230 reads (6%) | called by muse, mutect2
- ABCB6 | c.1095C>T p.R365= | Silent (SNP) | VAF 9/12 reads (75%) | called by muse, mutect2, varscan2
- ADAMTS12 | c.762C>T p.A254= | Silent (SNP) | VAF 741/1703 reads (44%) | catalogued as rs775100937, COSV61263775; called by muse, mutect2, varscan2
- ANKS6 | c.2058G>A p.R686= | Silent (SNP) | VAF 40/75 reads (53%) | catalogued as COSV62050411; called by muse, mutect2, varscan2
- CCDC110 | c.498C>T p.S166= | Silent (SNP) | VAF 67/180 reads (37%) | catalogued as rs761432896, COSV56871458; called by muse, mutect2, varscan2
- CMYA5 | c.10443G>A p.L3481= | Silent (SNP) | VAF 319/807 reads (40%) | catalogued as COSV101483967, COSV71406175; called by muse, mutect2, varscan2
- CPQ | c.426T>A p.P142= | Silent (SNP) | VAF 200/486 reads (41%) | catalogued as COSV55146773; called by muse, mutect2, varscan2
- ENPP2 | c.2433C>T p.D811= (on ENST00000075322 / NM_001040092.3; = p.D863= on NM_006209.5) | Silent (SNP) | VAF 46/1044 reads (4%) | catalogued as rs746246253, COSV50017325; called by muse, mutect2
- EPS8 | c.33T>C p.S11= | Silent (SNP) | VAF 12/184 reads (7%) | called by muse, mutect2
- GALNT18 | c.924C>T p.Y308= | Silent (SNP) | VAF 208/458 reads (45%) | catalogued as COSV57149845; called by muse, mutect2, varscan2
- GRIN3A | c.627C>T p.L209= | Silent (SNP) | VAF 106/144 reads (74%) | catalogued as COSV62454249; called by muse, mutect2, varscan2
- HTR3A | c.1332C>T p.R444= | Silent (SNP) | VAF 82/152 reads (54%) | catalogued as rs766338857, COSV55469643; called by muse, mutect2, varscan2
- KCNV1 | c.873G>A p.L291= | Silent (SNP) | VAF 12/134 reads (9%) | called by muse, mutect2
- LAMA1 | c.1620G>A p.P540= | Silent (SNP) | VAF 157/415 reads (38%) | catalogued as rs765638301, COSV67535741; called by muse, mutect2, varscan2
- MAGEB6B | c.774C>T p.S258= | Silent (SNP) | VAF 72/81 reads (89%) | catalogued as rs751739511; called by muse, mutect2, varscan2
- MUC17 | c.1251T>C p.P417= | Silent (SNP) | VAF 248/1001 reads (25%) | catalogued as COSV60289751; called by muse, mutect2, varscan2
- OR10G9 | c.795C>T p.D265= | Silent (SNP) | VAF 316/722 reads (44%) | catalogued as rs758211969, COSV66685718, COSV66685952; called by muse, mutect2, varscan2
- OR6M1 | c.651C>T p.Y217= | Silent (SNP) | VAF 141/320 reads (44%) | catalogued as rs1417385102, COSV58433711; called by muse, mutect2, varscan2
- POU1F1 | c.54C>T p.D18= | Silent (SNP) | VAF 88/202 reads (44%) | catalogued as rs1478435601, COSV60156018; called by muse, mutect2, varscan2
- RFPL2 | c.270C>T p.D90= | Silent (SNP) | VAF 193/259 reads (75%) | catalogued as COSV50711538; called by muse, mutect2, varscan2
- SIGLEC15 | c.738C>T p.S246= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV67181172; called by muse, mutect2, varscan2
- TRIM40 | c.567G>A p.A189= (on ENST00000376724; = p.A160= on NM_138700.4) | Silent (SNP) | VAF 86/129 reads (67%) | catalogued as rs759209501, COSV57156763; called by muse, mutect2, varscan2
